Somatic mutation profile of tumor specimen BA2190D (aliquot aq-BA2190D) from BEATAML1.0 case 2526, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,832 days).
Specimen BA2190D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fcad160-ae68-4e7e-8b7b-24d12d9c1551.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3022D (Solid Tissue Normal), aliquot aq-BA3022D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6d84428-b771-47c5-9aa9-7d1f81871ab6

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP7 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); catalogued as rs1434429381, COSV63505792; called by muse, mutect2, varscan2
- TXNDC5 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs564895754; called by muse, mutect2
- ACTR8 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2
- FAT1 | c.5324G>A p.S1775N | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAP2K4 | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR8H2 | c.712_715del p.F238Lfs*17 | Frame Shift Del (DEL) | VAF 29/251 reads (12%) | called by mutect2, pindel, varscan2
- TRIM28 | c.1924C>A p.Q642K | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2
- ZFP90 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.063); called by muse, mutect2
- KL | c.2427T>C p.Y809= | Silent (SNP) | VAF 43/505 reads (9%) | called by muse, mutect2
- KRT8 | c.1074C>T p.A358= | Silent (SNP) | VAF 15/243 reads (6%) | catalogued as rs541743394, COSV53176658; called by muse, mutect2
- PKD1L2 | c.2310G>T p.V770= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- NR6A1 | c.143-41227T>C | Intron (SNP) | VAF 9/264 reads (3%) | called by muse, mutect2
